CCDI case PBCGFC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77f9dba2-9ee2-4ce0-9a55-1859127dd42f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.6 years (1,692 days).

Biospecimens (3 samples)
- Samples 0DR9BU, 0DR9CE (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9CW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
